Somatic mutation profile of tumor specimen 0E1HF4 from CCDI case PBCWFK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1HF4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ba5bdb9-f57f-484b-8cbb-09dfa675845c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1HG0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6829bd4-997e-482d-94b3-cff619306c47

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 3, Nonsense Mutation 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IBA57 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 78/518 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs754055370; called by muse, mutect2, varscan2
- KBTBD4 | c.880A>T p.I294F | Missense Mutation (SNP) | VAF 126/310 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as COSV58596870; called by muse, mutect2, varscan2
- LIG3 | c.2870G>A p.R957H | Missense Mutation (SNP) | VAF 20/549 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1370270201, COSV52007436; called by muse, mutect2
- OR52L1 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 74/852 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs1479127176; called by muse, mutect2
- SPATS2L | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 63/1061 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as rs1194126462, COSV62354372; called by muse, mutect2
- DNAH2 | c.2005C>G p.R669G | Missense Mutation (SNP) | VAF 34/588 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- DPM2 | c.3+5G>C | Splice Region (SNP) | VAF 58/176 reads (33%) | called by muse, mutect2, varscan2
- GYPA | c.335dup p.Y112* | Nonsense Mutation (INS) | VAF 278/825 reads (34%) | called by mutect2, pindel, varscan2
- NFAT5 | c.4447_4448del p.G1483Pfs*32 | Frame Shift Del (DEL) | VAF 159/783 reads (20%) | called by mutect2, pindel, varscan2
- SLAMF6 | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 143/302 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD5 | c.282C>T p.S94= | Silent (SNP) | VAF 76/666 reads (11%) | catalogued as rs1180054634, COSV52427695; called by muse, mutect2, varscan2
- CHM | c.1812C>T p.F604= | Silent (SNP) | VAF 32/501 reads (6%) | called by muse, mutect2
- OR14I1 | c.240C>T p.I80= | Silent (SNP) | VAF 66/553 reads (12%) | called by muse, mutect2, varscan2
- SLC45A2 | c.741G>A p.K247= | Silent (SNP) | VAF 34/650 reads (5%) | called by muse, mutect2
- C8orf33 | c.550+19G>C | Intron (SNP) | VAF 37/322 reads (11%) | called by muse, mutect2, varscan2
- DST | c.4297-2714A>G | Intron (SNP) | VAF 410/974 reads (42%) | called by muse, mutect2, varscan2
- PGGHG | c.1481-22A>T | Intron (SNP) | VAF 18/157 reads (11%) | called by muse, mutect2
